National Lung Screening Trial (NLST) participant 218777 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: female; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, no significant abnormalities.
- T1 (day 357): Negative screen, no significant abnormalities.
- T2 (day 776): Negative screen, significant abnormalities not suspicious for lung cancer.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a negative screen; study year of the first confirmed lung cancer: T2; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 807, study year T2. Site: lung, NOS (ICD-O-3 C34.9), determined from cytology. Primary tumour location: left upper lobe, left lower lobe, other location. Histology: adenocarcinoma, NOS (ICD-O-3 8140/6, malignant, metastatic site). AJCC 6th edition staging: stage IV (best stage, from pathologic TNM); clinical T4 N2 M1 (stage IV); pathologic T4 N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T2 N2 M1a; pathologic TX NX M1a. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 807 (for ACRIN participants with lung cancer this field holds the diagnosis date).
